Somatic mutation profile of tumor specimen C3L-03733-01 (aliquot CPT0388870006) from CPTAC case C3L-03733, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.0 years (24,116 days).
Specimen C3L-03733-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5da8ca0e-6237-4594-92ef-cddc9f50750a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03733-31 (Blood Derived Normal), aliquot CPT0388900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b5d6636-da6f-4510-9ca9-3043096a6f84

The open-access MAF lists 73 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 2, Intron 2, Splice Region 1, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 341/410 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV52672087, COSV52843475, COSV52949919; called by muse, mutect2, varscan2
- ADGRL4 | c.1614T>A p.Y538* | Nonsense Mutation (SNP) | VAF 76/207 reads (37%) | catalogued as COSV66060724; called by muse, mutect2, varscan2
- ALCAM | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.949); catalogued as rs762442983; called by muse, mutect2, varscan2
- ANXA6 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1281762139; called by muse, mutect2, varscan2
- ATP6V1B1 | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 192/513 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52269864; called by muse, mutect2, varscan2
- CAPN11 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs781216695; called by muse, mutect2, varscan2
- CTNNA2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs377364195; called by muse, mutect2, varscan2
- FAM187B | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.149); catalogued as rs759026876; called by muse, mutect2, varscan2
- FBXW5 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56403868; called by muse, mutect2, varscan2
- GABRG2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.649); catalogued as rs772800839, COSV62716849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.3472C>T p.R1158W | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1179858347, COSV74204812; called by muse, mutect2, varscan2
- H1-8 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 132/402 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs557929114; called by muse, mutect2, varscan2
- HIVEP3 | c.6023del p.P2008Qfs*180 | Frame Shift Del (DEL) | VAF 48/126 reads (38%) | catalogued as rs1245904908; called by mutect2, pindel, varscan2
- KDM4E | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.297); catalogued as rs782315057; called by muse, mutect2, varscan2
- NLGN2 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 209/500 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.371); catalogued as rs1268279421, COSV57211658; called by muse, mutect2, varscan2
- NLRP13 | c.2963C>T p.A988V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs201165184, COSV61621240; called by muse, mutect2, varscan2
- OTOG | c.8669G>A p.R2890H | Missense Mutation (SNP) | VAF 42/581 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs375127426, COSV68039117; called by muse, mutect2
- PALB2 | c.1005T>G p.N335K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV99848453; called by muse, mutect2, varscan2
- PCNT | c.9535G>T p.V3179L | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs746610857, COSV100855027, COSV64029970; called by muse, mutect2, varscan2
- PHYHD1 | c.629C>T p.A210V (on ENST00000372592 / NM_001100876.2; = p.R203C on NM_174933.4) | Missense Mutation (SNP) | VAF 141/363 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs556760788, COSV100455272; called by muse, mutect2, varscan2
- PLXND1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 192/394 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs542362609; called by muse, mutect2, varscan2
- PPFIBP1 | c.971G>A p.R324Q (on ENST00000318304 / NM_177444.3; = p.R304Q on NM_003622.4) | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs868105358; called by muse, mutect2, varscan2
- PTPRC | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as rs1345142310, COSV100722009, COSV61407367; called by muse, mutect2, varscan2
- SH3TC1 | c.171C>T p.G57= | Splice Region (SNP) | VAF 32/54 reads (59%) | catalogued as rs149263292; called by muse, mutect2, varscan2
- TTC6 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs1260320827; called by muse, mutect2, varscan2
- WDFY4 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 68/89 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs749750781, COSV57440152, COSV57449792; called by muse, mutect2, varscan2
- ZNF558 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs151066007; called by muse, mutect2, varscan2
- ACSM2B | c.1102T>A p.L368I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CAMSAP1 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CDCA2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNPY3 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPN1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 240/325 reads (74%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KLK2 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- KRTAP2-1 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 144/317 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MARS1 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 218/3148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- NKX2-1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 129/159 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- OR2F1 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- OTOG | c.5599G>T p.A1867S | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PALM3 | c.1782del p.A595Lfs*127 (on ENST00000340790; = p.A610Lfs*127 on NM_001145028.2) | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.2152A>T p.R718W | Missense Mutation (SNP) | VAF 210/474 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PKD1L3 | c.4917C>G p.H1639Q | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PRKDC | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 64/219 reads (29%) | called by muse, mutect2, varscan2
- PTEN | c.170dup p.L57Ffs*6 | Frame Shift Ins (INS) | VAF 45/77 reads (58%) | called by mutect2, pindel, varscan2
- RPS28 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SEMA3D | c.1593G>T p.L531F | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SEMA4D | c.477C>G p.D159E | Missense Mutation (SNP) | VAF 138/363 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- SLC26A3 | c.2222T>A p.I741N | Missense Mutation (SNP) | VAF 113/424 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFF3 | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 37/504 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- TMEM245 | c.262G>C p.V88L | Missense Mutation (SNP) | VAF 149/377 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- TRIM56 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCDC63 | c.1494A>G p.K498= | Silent (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- CD3D | c.309C>T p.T103= | Silent (SNP) | VAF 110/342 reads (32%) | catalogued as rs777386322; ClinVar: likely benign; called by muse, varscan2
- FLG | c.7446A>G p.V2482= | Silent (SNP) | VAF 248/578 reads (43%) | called by muse, mutect2
- KIT | c.978C>T p.N326= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs148594615; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2
- LRRC7 | c.1065T>A p.T355= (on ENST00000651989 / NM_001370785.2; = p.T322= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 109/281 reads (39%) | called by muse, mutect2, varscan2
- MYO18B | c.1212C>T p.N404= | Silent (SNP) | VAF 99/261 reads (38%) | catalogued as rs772481621; called by muse, mutect2, varscan2
- NKX6-3 | c.60G>A p.P20= | Silent (SNP) | VAF 114/285 reads (40%) | catalogued as rs1315904214; called by muse, mutect2, varscan2
- NYAP2 | c.1470C>T p.A490= | Silent (SNP) | VAF 155/390 reads (40%) | catalogued as rs779818817, COSV56014924; called by muse, mutect2, varscan2
- OR6B3 | c.282C>T p.F94= | Silent (SNP) | VAF 91/265 reads (34%) | catalogued as rs751578693, COSV60113642; called by muse, mutect2, varscan2
- PCLO | c.13665A>G p.V4555= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as rs1400290889; called by muse, mutect2, varscan2
- PICK1 | c.915C>G p.R305= | Silent (SNP) | VAF 166/477 reads (35%) | called by muse, mutect2, varscan2
- PLXNB2 | c.4764G>T p.V1588= | Silent (SNP) | VAF 132/288 reads (46%) | called by muse, mutect2, varscan2
- R3HDM2 | c.264C>T p.T88= | Silent (SNP) | VAF 96/227 reads (42%) | called by muse, mutect2, varscan2
- RNF207 | c.1446C>T p.H482= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as rs372120591; called by muse, mutect2, varscan2
- SPTB | c.4188C>T p.S1396= | Silent (SNP) | VAF 211/284 reads (74%) | catalogued as rs200909666; called by muse, mutect2, varscan2
- UCKL1 | c.1470C>T p.G490= | Silent (SNP) | VAF 140/398 reads (35%) | catalogued as rs1254100712; called by muse, mutect2, varscan2
- WDR62 | c.375C>T p.Y125= | Silent (SNP) | VAF 153/385 reads (40%) | called by muse, mutect2, varscan2
- APTX | c.*363C>A | 3'UTR (SNP) | VAF 127/294 reads (43%) | called by muse, mutect2, varscan2
- ETS2 | c.-239C>G | 5'UTR (SNP) | VAF 123/286 reads (43%) | called by muse, mutect2, varscan2
- FAM227B | c.1013-24936G>A | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as rs905603772; called by muse, mutect2, varscan2
- KCNQ1 | c.387-6424C>T | Intron (SNP) | VAF 34/96 reads (35%) | catalogued as rs770840284; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159316 C>A | 5'Flank (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- UCMA | c.-16C>T | 5'UTR (SNP) | VAF 66/91 reads (73%) | called by muse, mutect2, varscan2
